Somatic mutation profile of tumor specimen MMRF_2731_1_BM_CD138pos (aliquot MMRF_2731_1_BM_CD138pos_T1_KHS5U_L14874) from MMRF case MMRF_2731, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.1 years (22,700 days).
Specimen MMRF_2731_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a052d726-4faa-42cf-87f2-a49758743b8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2731_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2731_1_PB_WBC_C3_KHS5U_L14875; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/959614db-8141-473f-9283-e26fa27aceee

The open-access MAF lists 141 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 44, Intron 15, Silent 12, 5'UTR 6, RNA 5, Nonsense Mutation 4, 5'Flank 3, 3'Flank 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG12 | c.230del p.R77Qfs*28 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV57243365; called by mutect2, pindel, varscan2
- AXIN2 | c.1892A>C p.K631T | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs139945372; called by muse, mutect2, varscan2
- BOC | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs759609900; called by muse, mutect2, varscan2
- CACNA1H | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs915582991; called by muse, mutect2, varscan2
- CEP20 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs145630355; called by muse, mutect2, varscan2
- CHTF18 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770120244; called by muse, mutect2, varscan2
- CTTNBP2 | c.4718A>G p.N1573S | Missense Mutation (SNP) | VAF 94/301 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV50391354; called by muse, mutect2, varscan2
- DMD | c.5008T>G p.W1670G | Missense Mutation (SNP) | VAF 75/81 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs973159625; called by muse, mutect2, varscan2
- EXD3 | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.164); catalogued as rs1452425333; called by muse, mutect2, varscan2
- FKBP6 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 124/489 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99333613; called by muse, mutect2, varscan2
- GNA15 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV99504953; called by muse, mutect2, varscan2
- GPLD1 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs760858079, COSV57761806; called by muse, mutect2, varscan2
- IGHV4-34 | c.183C>G p.S61R | Missense Mutation (SNP) | VAF 159/173 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs11546809; called by muse, mutect2, varscan2
- ISM2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs201324121, COSV53635766; called by muse, mutect2, varscan2
- KRTAP3-3 | c.283C>G p.P95A | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.385); catalogued as COSV66956635; called by muse, mutect2, varscan2
- LAMB1 | c.4258G>C p.E1420Q | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV55967593; called by muse, mutect2, varscan2
- LGR5 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 168/351 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs763341471, COSV57011143; called by muse, mutect2, varscan2
- MAK | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs371774117; called by muse, mutect2, varscan2
- MYL10 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs776182712; called by muse, mutect2, varscan2
- NOTCH2 | c.2066A>G p.N689S | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs782325711, COSV56695686; called by muse, mutect2, varscan2
- NPAP1 | c.2558G>T p.G853V | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61504140; called by muse, mutect2, varscan2
- PEG3 | c.4702G>A p.V1568I | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs191716523; called by muse, mutect2, varscan2
- RD3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100879208; called by muse, mutect2, varscan2
- RGS7 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 181/625 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1181998043, COSV58537763; called by muse, mutect2, varscan2
- SARDH | c.693C>T p.V231= | Splice Region (SNP) | VAF 129/365 reads (35%) | catalogued as COSV53832012; called by muse, mutect2, varscan2
- SLC27A4 | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540906829, COSV55959322; called by muse, mutect2, varscan2
- TMEM161A | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762042451; called by muse, mutect2, varscan2
- TPSG1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs775393068; called by muse, mutect2, varscan2
- VPS39 | c.2194G>C p.D732H (on ENST00000348544 / NM_001301138.2; = p.D721H on NM_015289.5) | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV58793167; called by muse, mutect2, varscan2
- VWA5B2 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1484160139, COSV56613969; called by muse, mutect2, varscan2
- ADAMTS5 | c.1577A>C p.Q526P | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- ANKRD55 | c.1748C>A p.T583K | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); called by muse, mutect2
- ATG9B | c.1852C>A p.Q618K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, varscan2
- ATP6V1G1 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATR | c.4113C>G p.F1371L | Missense Mutation (SNP) | VAF 142/483 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIDEA | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF8L1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX51 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DNAH3 | c.10150C>G p.Q3384E | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPRX | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 123/368 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLT1D1 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 97/212 reads (46%) | called by muse, mutect2, varscan2
- GPSM1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- JAG1 | c.658T>C p.C220R | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNIP4 | c.212A>C p.E71A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- LONP2 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 57/61 reads (93%) | called by muse, mutect2, varscan2
- MAGEB18 | c.264A>C p.Q88H | Missense Mutation (SNP) | VAF 92/98 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- MAGEB4 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MUC5B | c.13963A>T p.T4655S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTPRD | c.5125A>C p.R1709= | Splice Region (SNP) | VAF 91/290 reads (31%) | called by muse, mutect2, varscan2
- SVEP1 | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 114/319 reads (36%) | called by muse, mutect2, varscan2
- SVIL | c.2131C>G p.Q711E (on ENST00000355867 / NM_021738.3; = p.Q317E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM39A | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WEE1 | c.870T>G p.N290K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2
- ZCCHC2 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ASTN2 | c.2973C>T p.R991= (on ENST00000313400 / NM_001365069.1; = p.R940= on NM_014010.5) | Silent (SNP) | VAF 88/138 reads (64%) | called by muse, mutect2, varscan2
- CCDC166 | c.513G>A p.E171= | Silent (SNP) | VAF 50/98 reads (51%) | called by muse, mutect2, varscan2
- CHORDC1 | c.717T>G p.G239= | Silent (SNP) | VAF 22/52 reads (42%) | called by mutect2, varscan2
- GRM1 | c.2151A>G p.Q717= | Silent (SNP) | VAF 88/190 reads (46%) | catalogued as rs1378924113, COSV51110865; called by muse, mutect2, varscan2
- GTF2E1 | c.46C>A p.R16= | Silent (SNP) | VAF 36/622 reads (6%) | called by muse, mutect2
- IGSF11 | c.645C>T p.C215= (on ENST00000393775 / NM_001015887.3; = p.C214= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/145 reads (58%) | catalogued as rs762548204, COSV61170929; called by muse, mutect2, varscan2
- ISLR | c.1023C>T p.D341= | Silent (SNP) | VAF 113/279 reads (41%) | catalogued as rs780616088; called by muse, mutect2, varscan2
- MCM3AP | c.54T>C p.S18= | Silent (SNP) | VAF 171/355 reads (48%) | called by muse, mutect2, varscan2
- NF1 | c.3297A>G p.K1099= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1761G>A p.E587= | Silent (SNP) | VAF 60/197 reads (30%) | catalogued as rs1378333737; called by muse, mutect2, varscan2
- SH3BP4 | c.1521C>T p.S507= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as rs757070908; called by muse, mutect2, varscan2
- STK31 | c.2913T>C p.C971= | Silent (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- ADCY2 | c.*1621G>T | 3'UTR (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2, varscan2
- ADCY2 | c.*1622G>T | 3'UTR (SNP) | VAF 62/255 reads (24%) | called by muse, mutect2, varscan2
- API5 | c.*1292C>T | 3'UTR (SNP) | VAF 74/583 reads (13%) | called by muse, mutect2, varscan2
- ARL6IP1 | c.*1406A>C | 3'UTR (SNP) | VAF 144/332 reads (43%) | called by muse, mutect2, varscan2
- ARSD | c.1000+920_1000+945del | Intron (DEL) | VAF 27/47 reads (57%) | called by mutect2, pindel, varscan2
- ATP12A | c.-178C>T | 5'UTR (SNP) | VAF 17/21 reads (81%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*3226A>C | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- C2CD2L | c.*1568C>A | 3'UTR (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- CDH18 | c.*5T>G | 3'UTR (SNP) | VAF 147/320 reads (46%) | called by muse, mutect2, varscan2
- CIT | c.*1846C>A | 3'UTR (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- CREM | c.508+320C>A | Intron (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- CTCFL | c.*26G>A | 3'UTR (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- DKK2 | c.*1278A>G | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- DRD5 | c.-268C>T | 5'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- EFNA5 | c.418+71C>T | Intron (SNP) | VAF 99/311 reads (32%) | called by muse, mutect2, varscan2
- EMCN | c.-34G>T | 5'UTR (SNP) | VAF 47/145 reads (32%) | called by muse, mutect2, varscan2
- FAM193A | c.*171T>A | 3'UTR (SNP) | VAF 74/268 reads (28%) | called by muse, mutect2, varscan2
- FOXD1 | c.-38G>C | 5'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+18308C>T | Intron (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- GCSAML | c.*3272del | 3'UTR (DEL) | VAF 19/116 reads (16%) | called by mutect2, pindel, varscan2
- GIMAP6 | c.*1565C>A | 3'UTR (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
- GLUD1P3 | n.313-9C>T | Intron (SNP) | VAF 162/366 reads (44%) | called by muse, mutect2, varscan2
- GRM1 | c.*885A>G | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, varscan2
- GRM1 | c.*1033A>G | 3'UTR (SNP) | VAF 44/96 reads (46%) | called by muse, varscan2
- HES2 | c.*651T>C | 3'UTR (SNP) | VAF 102/244 reads (42%) | called by muse, mutect2, varscan2
- HIPK3 | c.*40G>A | 3'UTR (SNP) | VAF 80/170 reads (47%) | called by muse, varscan2
- IGFBP2 | c.673-48G>A | Intron (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- IYD | c.*7000C>G | 3'UTR (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- KCNG3 | c.*706G>A | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- KIF16B | c.*1142G>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- KIF22 | c.1450-29G>T | Intron (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- KRT80 | c.*1218C>A | 3'UTR (SNP) | VAF 10/125 reads (8%) | called by muse, mutect2
- LNPK | c.*5439T>A | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- LY6H | chr8:143160315 C>G | 5'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*362T>C | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- MEGF9 | c.*1704G>A | 3'UTR (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- MIR3680-1 | chr16:21502272 G>T | 3'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as rs1411575394; called by muse, mutect2
- MUC16 | c.-91A>T | 5'UTR (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- MYEF2 | c.*2105G>C | 3'UTR (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- MYLIP | c.*529A>T | 3'UTR (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- NACAD | c.4258-50del | Intron (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- NDN | c.*277A>C | 3'UTR (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+1719G>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- ODR4 | c.*2007G>A | 3'UTR (SNP) | VAF 37/111 reads (33%) | catalogued as rs1222430000; called by muse, mutect2, varscan2
- PATE1 | c.53-8del | Intron (DEL) | VAF 53/124 reads (43%) | catalogued as rs745805577; called by mutect2, varscan2
- PDCD6IPP1 | n.171G>C | RNA (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
- PELP1 | chr17:4704346 C>T | 5'Flank (SNP) | VAF 29/73 reads (40%) | catalogued as rs1044703984; called by muse, mutect2, varscan2
- PEX26 | c.*2485C>A | 3'UTR (SNP) | VAF 111/235 reads (47%) | called by muse, mutect2, varscan2
- PLXNA2 | c.*4982A>G | 3'UTR (SNP) | VAF 32/74 reads (43%) | catalogued as rs1349198222; called by muse, mutect2, varscan2
- PPARGC1B | c.*1244G>A | 3'UTR (SNP) | VAF 49/151 reads (32%) | called by muse, mutect2, varscan2
- RABL6 | c.131-1495G>A | Intron (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.699-53C>G | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- RBP3 | c.*159A>C | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- RFTN2 | c.*656C>G | 3'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2
- RNASEK | c.196-71G>A | Intron (SNP) | VAF 18/318 reads (6%) | catalogued as rs1485759342; called by muse, mutect2
- RPRM | c.*758A>G | 3'UTR (SNP) | VAF 57/136 reads (42%) | called by muse, mutect2, varscan2
- SEMA3E | c.*2904A>C | 3'UTR (SNP) | VAF 62/100 reads (62%) | called by muse, mutect2, varscan2
- SFTA3 | n.810-843C>G | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- SORL1 | c.*1406A>G | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- SSPOP | n.12797A>C | RNA (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- SSPOP | n.12798G>T | RNA (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- STAG3L4 | n.778T>C | RNA (SNP) | VAF 194/713 reads (27%) | called by muse, varscan2
- TEX10 | c.-10+322G>A | Intron (SNP) | VAF 90/329 reads (27%) | called by muse, mutect2, varscan2
- TEX35 | c.*573G>A | 3'UTR (SNP) | VAF 145/236 reads (61%) | catalogued as rs949536259; called by muse, mutect2, varscan2
- TMEM164 | c.*3166G>A | 3'UTR (SNP) | VAF 42/46 reads (91%) | called by muse, mutect2, varscan2
- TMEM258 | c.-8G>A | 5'UTR (SNP) | VAF 21/376 reads (6%) | catalogued as rs763696400, COSV53893013; called by muse, mutect2
- TRAIP | c.*115G>A | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- TRIM31 | c.*134G>A | 3'UTR (SNP) | VAF 58/186 reads (31%) | called by muse, mutect2, varscan2
- TTBK1 | c.*1312G>A | 3'UTR (SNP) | VAF 79/167 reads (47%) | called by muse, mutect2, varscan2
- UFL1 | c.*818G>T | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- WBP11 | c.*361A>T | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- XRN2 | chr20:21303274 C>A | 5'Flank (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- ZMAT2 | c.*117G>A | 3'UTR (SNP) | VAF 64/186 reads (34%) | called by muse, mutect2, varscan2
- ZNF131 | chr5:43176192 del GT | 3'Flank (DEL) | VAF 42/208 reads (20%) | called by pindel, varscan2
- ZNF725P | n.966G>T | RNA (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
